Surgical pathology report (de-identified scan), TCGA case TCGA-S7-A7WR, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University Hospital Motol, specimen TCGA-S7-A7WR-01A (Primary Tumor).

Gross:

Thinly fibrously encapsulated ovoid tumor of soft consistency 55x45x35 mm, weight 50 g.

On cut, the tumor is grey-red, with focal hemorrhages.

Micro:

Solidly alveolarly shaped right pheochromocytoma with focal hemorrhages and with rim of adrenocortical tissue on periphery was confirmed in excisions. The tumor does not invade adrenal capsule in to surrounding adipose tissue. It shows nuclear hyperchromasia sporadically, no regular or atypical mitoses were found. No necroses were found.

Staining for S100 protein weakly to moderately positive pheochromocytoma cells, strong positive sustentacular cells.

MIB1 <1% positive cells.

PASS

Large nests or diffuse growth (>10% of tumor volume)

Central (middle of large nests) or confluent tumor necrosis

High cellularity

Cellular monotony

Tumor cell spindling (even if focal) 1

Mitotic figures >3/10 HPF

Atypical mitotic figure(s)

Extension into adipose tissue

Vascular invasion

Capsular invasion

Profound nuclear pleomorphism

Nuclear hyperchromasia

Total 1

Procurement date:

Confirmation date:

ICD-O-3

40 pheochromocytoma NOS 8700/0

Site @ Adrenal gland 274.9

9/10/9/13

Reviewer Initials	BAF	Reviewed: 9/13/13

Source: NCI Genomic Data Commons file 722355e0-2f73-4b53-916f-a499e21c78fc (TCGA-S7-A7WR.048DD97F-E3D4-4EDF-BF5A-ACAAC87A54A8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).